Gene-level copy-number profile of tumor specimen TCGA-ZG-A9NI-01A from TCGA case TCGA-ZG-A9NI, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 73.1 years (26,697 days).
Specimen TCGA-ZG-A9NI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.482b5252-2960-47ae-9b90-d86c5b5b1ea8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZG-A9NI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/35d97afa-177e-44e8-9172-0c633fec8bdb

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 2: 5,468; copy number 3: 1,834; copy number 4: 30,888; copy number 5: 12,909; copy number 6: 5,861; copy number 7: 1,585; copy number 9: 1,085; copy number 12: 156.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZG-A9NI-01A-11D-A41J-01): tumor purity 0.45, ploidy 4.39, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:31,838,752–33,676,796, 31 genes: AL138708.1, FRY, EEF1DP3, AC002525.1, Metazoa_SRP, FRY-AS1, ZAR1L, BRCA2, IFIT1P1, N4BP2L1, AL137247.1, AL137247.2, N4BP2L2, ATP8A2P2, N4BP2L2-IT2, PDS5B, RNY1P4, AL138820.1, LINC00423, TOMM22P3, KL, STARD13, STARD13-IT1, STARD13-AS, AL627232.1, LINC02344, AL138999.2, AL138999.1, AL139383.1, AL161719.1, AL139081.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,241 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:66,126,896–145,066,685, 1,241 genes, copy number 9–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
